Somatic mutation profile of tumor specimen TCGA-HC-7748-01A (aliquot TCGA-HC-7748-01A-11D-2114-08) from TCGA case TCGA-HC-7748, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 60.4 years (22,072 days).
Specimen TCGA-HC-7748-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2829057-67c2-41d4-a960-139686322e0d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-7748-10A (Blood Derived Normal), aliquot TCGA-HC-7748-10A-01D-2115-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88c7e3e3-9d0c-41d4-9e76-003dc298e91b

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 4, Frame Shift Del 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.1091G>A p.S364N | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56992103; called by muse, mutect2, varscan2
- CA3 | c.173C>A p.T58N | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.32); catalogued as COSV53410058; called by muse, mutect2
- CACNA1E | c.2836C>T p.R946C | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs757105337, COSV62395307; called by muse, mutect2, varscan2
- EPHX3 | c.998C>A p.P333Q | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV55655684; called by muse, varscan2
- FOXJ2 | c.758G>C p.W253S | Missense Mutation (SNP) | VAF 44/217 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.19); catalogued as COSV50817703, COSV50819296; called by muse, mutect2, varscan2
- LILRA6 | c.608C>T p.T203I | Missense Mutation (SNP) | VAF 37/253 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.804); catalogued as rs1232578662, COSV54433607; called by muse, mutect2, varscan2
- LSR | c.923T>C p.L308P (on ENST00000361790; = p.L289P on NM_015925.6) | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV55887248; called by muse, mutect2, varscan2
- NTM | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.196); catalogued as rs748845604, COSV66181446; called by muse, mutect2, varscan2
- PAPPA | c.3952G>T p.A1318S | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60284639; called by muse, mutect2
- RPAP2 | c.1312G>C p.G438R | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV72509379; called by muse, mutect2, varscan2
- SIAH3 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs376694319; called by muse, mutect2, varscan2
- TRIM4 | c.592A>G p.R198G | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV62469400; called by muse, mutect2, varscan2
- UBD | c.236A>G p.K79R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.88); PolyPhen benign (0.003); catalogued as rs1259434002, COSV63542732; called by muse, mutect2, varscan2
- XKR4 | c.1765C>T p.R589W | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs371310690; called by muse, mutect2, varscan2
- ZNF502 | c.331A>G p.T111A | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.458); catalogued as COSV56073821; called by muse, mutect2
- ZNF532 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60172139; called by muse, mutect2, varscan2
- OTULINL | c.283_286del p.D95Yfs*18 | Frame Shift Del (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- ZCCHC3 | c.778del p.R260Gfs*11 | Frame Shift Del (DEL) | VAF 22/98 reads (22%) | called by mutect2, pindel, varscan2
- CNGA1 | c.1731C>G p.L577= | Silent (SNP) | VAF 58/226 reads (26%) | catalogued as COSV62054581; called by muse, mutect2, varscan2
- EPB41L2 | c.1329G>A p.P443= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs376962561; called by muse, mutect2, varscan2
- HCAR2 | c.915C>T p.F305= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs772499305, COSV61025026; called by muse, mutect2, varscan2
- PPIG | c.1290A>G p.K430= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs1339071664, COSV53643534; called by muse, mutect2, varscan2
- NRP2 | c.2440+9684G>A | Intron (SNP) | VAF 11/178 reads (6%) | catalogued as COSV55929477; called by muse, mutect2
